TCGA case TCGA-5V-A9RR — Thymoma (TCGA-THYM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Thymic Epithelial Neoplasms; Primary site: Thymus; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bfe41ba3-2bcf-4760-ae65-cd417e22393f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Thymoma, type AB, NOS: ICD-O-3 morphology code: 8582/1; ICD-10 code: C37; Tissue or organ of origin: Thymus; Site of resection or biopsy: Thymus; Classification of tumor: primary; Age at diagnosis: 67.5 years (24,668 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; Masaoka stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 827 days (2.3 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 532 days (1.5 years); Disease response: Tumor Free.
- Days to follow up: 827 days (2.3 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 93 kg; Height: 176 cm; BMI: 30.
- Timepoint category: Prior to Diagnosis; Comorbidities: Myasthenia Gravis; Risk factors: Myasthenia Gravis.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-5V-A9RR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 210 mg.
  Slide TCGA-5V-A9RR-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-5V-A9RR-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-5V-A9RR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Stage record: Masaoka stage: I.
- Primary pathology, Histological type list: Histologic diagnosis: Thymoma, Type AB.
- Primary pathology: Method initial path diagnosis: Median Sternectomy; History myasthenia gravis: Yes.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 827 days; disease-specific survival: no event (censored), 827 days; progression-free interval: no event (censored), 827 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-5V-A9RR-01A-11D-A422-01): tumor purity 0.54, ploidy 1.99, whole-genome doublings 0.
